Somatic mutation profile of tumor specimen TCGA-A3-3316-01A (aliquot TCGA-A3-3316-01A-01D-0966-08) from TCGA case TCGA-A3-3316, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 57.3 years (20,931 days).
Specimen TCGA-A3-3316-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69ba2041-68fc-427a-a702-b88858f95159.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3316-11A (Solid Tissue Normal), aliquot TCGA-A3-3316-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88a80830-7588-4ffb-b2cf-d991f66cc187

The open-access MAF lists 39 somatic variants for this specimen: 34 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Frame Shift Del 4, Silent 3, Nonsense Mutation 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 80/246 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM110142, COSV64288690, COSV64296946; called by muse, mutect2, varscan2
- ABCB5 | c.3403del p.H1135Ifs*17 (on ENST00000404938 / NM_001163941.2; = p.H690Ifs*17 on NM_178559.6) | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | catalogued as COSV51707726; called by mutect2, pindel, varscan2
- ARID5B | c.1999A>C p.N667H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54413462; called by muse, mutect2, varscan2
- ATP13A4 | c.1543T>C p.F515L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV55065561; called by muse, mutect2, varscan2
- CCDC181 | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV63155564; called by muse, mutect2, varscan2
- CD300E | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV60789692; called by muse, varscan2
- CLDN4 | c.555T>G p.C185W | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV52894832; called by muse, mutect2, varscan2
- CRB1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754610149, COSV66328538; called by muse, mutect2, varscan2
- CYP4F12 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV61172165; called by muse, mutect2, varscan2
- DSG1 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 21/201 reads (10%) | catalogued as COSV57132998; called by muse, mutect2, varscan2
- DSG2 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55196474; called by muse, mutect2, varscan2
- EFCAB2 | c.540G>C p.R180S (on ENST00000366522; = p.R44S on NM_032328.3) | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV63655337; called by muse, mutect2, varscan2
- EPHX1 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55298446; called by muse, mutect2, varscan2
- FGA | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV57392484; called by muse, mutect2, varscan2
- GRIN2A | c.3832C>A p.Q1278K | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.185); catalogued as COSV58018710; called by muse, mutect2, varscan2
- GUCY1A1 | c.1009G>C p.G337R | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.127); catalogued as COSV56648752, COSV99638479; called by muse, mutect2, varscan2
- HSPA5 | c.1861A>G p.K621E | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.068); catalogued as rs773627521, COSV52333989; called by muse, mutect2, varscan2
- IGFL4 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV66618747; called by muse, mutect2, varscan2
- MLX | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV53815967, COSV99037666; called by muse, mutect2, varscan2
- MSH4 | c.2439A>C p.E813D | Missense Mutation (SNP) | VAF 8/250 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV54195964; called by muse, mutect2
- MTMR10 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV71188624; called by muse, mutect2, varscan2
- NNT | c.2795G>A p.G932D | Missense Mutation (SNP) | VAF 120/358 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52922363; called by muse, varscan2
- PEG3 | c.169T>A p.F57I | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV55623717; called by muse, mutect2, varscan2
- RASGEF1B | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1194190936, COSV52335228; called by muse, mutect2, varscan2
- RIMBP2 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.972); catalogued as rs141970284; called by muse, mutect2, varscan2
- SMCHD1 | c.2579A>G p.D860G | Missense Mutation (SNP) | VAF 47/479 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1568235349, COSV55251053; called by muse, mutect2
- SPTBN5 | c.2483G>C p.G828A | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.029); catalogued as COSV58015996; called by muse, mutect2, varscan2
- USF3 | c.1516A>G p.M506V | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV57069450; called by muse, mutect2, varscan2
- VHL | c.439del p.I147Ffs*12 | Frame Shift Del (DEL) | VAF 97/351 reads (28%) | catalogued as CM106926, COSV56543105, COSV56564700, COSV99846812; called by mutect2, pindel, varscan2
- ZC3H11A | c.1157C>A p.S386* | Nonsense Mutation (SNP) | VAF 19/123 reads (15%) | catalogued as COSV59744290; called by muse, mutect2, varscan2
- ZNF280C | c.2039T>A p.L680H | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV63968429; called by muse, mutect2, varscan2
- ZNF280C | c.2038C>T p.L680F | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV63968435; called by muse, mutect2, varscan2
- LRRC30 | c.897del p.K299Nfs*? | Frame Shift Del (DEL) | VAF 140/442 reads (32%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4510del p.V1505Lfs*34 (on ENST00000296302 / NM_001366071.2; = p.V1398Lfs*34 on NM_018313.5) | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13666C>T p.L4556= | Silent (SNP) | VAF 54/590 reads (9%) | catalogued as COSV68942915; called by muse, mutect2
- CUL5 | c.2163A>G p.Q721= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV67607963; called by muse, mutect2, varscan2
- FANCF | c.528G>A p.E176= | Silent (SNP) | VAF 38/290 reads (13%) | catalogued as rs1332270825, COSV59415554; called by muse, mutect2, varscan2
- FMNL1 | c.*38G>C | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- GLYATL1 | c.-98G>C | 5'UTR (SNP) | VAF 26/91 reads (29%) | catalogued as rs1337957661, COSV55606899; called by muse, mutect2, varscan2
